EXCEPTIONAL_RESPONDERS case ER-ADC2 — Exceptional Responders (EXCEPTIONAL_RESPONDERS-ER)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Ovary. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c43230bd-8340-4772-92e1-1ec5af77646a

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age: 90 years or older (exact value withheld by GDC); Vital status: Alive.

Diagnoses (1)
1. Carcinoma, NOS: ICD-O-3 morphology code: 8010/3; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Classification of tumor: metastasis; Age at diagnosis: 90 years or older (exact value withheld by GDC); Year of diagnosis: 2007; AJCC staging edition: 6th; AJCC pathologic stage: Stage IIIC; Prior malignancy: no; Days to last follow up: 2,733 days (7.5 years); Days to best overall response: 1,015 days (2.8 years); Best overall response: Complete Response.
   Treatment given: Therapeutic agents: Carboplatin + Paclitaxel; Days to treatment start: 35 days; Days to treatment end: 140 days.

Follow-up (1 entry)
- Days to follow up: 2,733 days (7.5 years); Disease response: Stable Disease; Progression or recurrence: Yes; Days to recurrence: 945 days (2.6 years); Days progression-free: 2,733 days (7.5 years).

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ER-ADC2-TTM1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: FFPE.
  Slide ER-ADC2-TTM1-A-1-0-S1: Section location: Top; Percent tumor cells: 15; Percent tumor nuclei: 20; Percent normal cells: 25; Percent necrosis: 0; Percent stromal cells: 60; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
